Somatic mutation profile of tumor specimen PCProject_0443_T2_WES (aliquot PCProject_0443_T2_WES_1) from CMI case PCProject_0443, project CMI-MPC: Count Me In (CMI): The Metastatic Prostate Cancer (MPC) Project. Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 76.3 years (27,860 days).
Specimen PCProject_0443_T2_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Prostate; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f3a7f222-196d-416d-be86-f6020cf2ef2d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen PCProject_0443_SALIVA (DNA), aliquot PCProject_0443_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/176c9358-6e31-4f4b-b656-890f69f6482b

The open-access MAF lists 30 somatic variants for this specimen: 20 protein-altering or splice-affecting, 5 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, Silent 5, Intron 4, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CFAP91 | c.1820G>A p.R607Q | Missense Mutation (SNP) | VAF 28/178 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs556802557, COSV99847345; called by muse, mutect2, varscan2
- FSIP2 | c.6779G>A p.R2260H | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs868232372; called by muse, mutect2, varscan2
- KIAA2026 | c.3226A>G p.I1076V | Missense Mutation (SNP) | VAF 15/172 reads (9%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as rs767824157; called by muse, mutect2
- LRCH1 | c.1356C>G p.I452M | Missense Mutation (SNP) | VAF 27/152 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.972); catalogued as rs761088818; called by muse, mutect2, varscan2
- MKI67 | c.4514C>T p.T1505I | Missense Mutation (SNP) | VAF 47/409 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.372); catalogued as rs1429772364; called by muse, mutect2, varscan2
- MYO1G | c.1333G>A p.V445I | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs758264063; called by muse, varscan2
- NFIB | c.738C>A p.S246R | Missense Mutation (SNP) | VAF 68/402 reads (17%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.899); catalogued as rs1449064947; called by muse, mutect2, varscan2
- ZNF253 | c.354C>G p.S118R | Missense Mutation (SNP) | VAF 14/182 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.012); catalogued as rs1044280022, COSV100849459; called by muse, mutect2
- AP4M1 | c.334C>T p.L112F | Missense Mutation (SNP) | VAF 54/544 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- FCRLB | c.460A>G p.T154A | Missense Mutation (SNP) | VAF 20/185 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.675); called by muse, mutect2, varscan2
- GPR152 | c.1033A>G p.M345V | Missense Mutation (SNP) | VAF 62/532 reads (12%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2, varscan2
- IL1R1 | c.180T>A p.D60E | Missense Mutation (SNP) | VAF 47/281 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- PCF11 | c.523A>T p.T175S | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.6); PolyPhen benign (0.039); called by muse, mutect2
- TEX13A | c.768G>T p.K256N | Missense Mutation (SNP) | VAF 86/204 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TEX15 | c.390G>A p.M130I (on ENST00000256246; = p.M513I on NM_001350162.2) | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TIPIN | c.317A>C p.H106P | Missense Mutation (SNP) | VAF 9/93 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); called by muse, mutect2
- TMEM45A | c.241G>A p.D81N | Missense Mutation (SNP) | VAF 18/364 reads (5%) | SIFT tolerated (0.61); PolyPhen benign (0.017); called by muse, mutect2
- ZNF267 | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 38/371 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); called by muse, mutect2
- ZNF41 | c.1451T>C p.V484A | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.215); called by muse, mutect2, varscan2
- ZSCAN9 | c.407A>G p.E136G | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); called by muse, varscan2
- AGAP2 | c.1539G>A p.V513= (on ENST00000547588 / NM_001122772.2; = p.V177= on NM_014770.4) | Silent (SNP) | VAF 4/28 reads (14%) | called by muse, mutect2
- CSMD2 | c.10281C>T p.F3427= | Silent (SNP) | VAF 63/361 reads (17%) | catalogued as rs770991666, COSV53951035; called by muse, mutect2, varscan2
- GRIA2 | c.909C>T p.A303= | Silent (SNP) | VAF 10/32 reads (31%) | catalogued as rs767317250, COSV52387660; called by muse, mutect2, varscan2
- HSD3B7 | c.558G>A p.T186= | Silent (SNP) | VAF 132/490 reads (27%) | catalogued as rs760192112, COSV52679734; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NOVA2 | c.1191G>A p.A397= | Silent (SNP) | VAF 13/362 reads (4%) | called by muse, mutect2
- AC244517.10 | c.36-8951G>A | Intron (SNP) | VAF 38/1208 reads (3%) | catalogued as rs782808498; called by muse, mutect2
- CCT3 | c.31+1001A>G | Intron (SNP) | VAF 11/111 reads (10%) | catalogued as rs1291738365; called by muse, mutect2
- KATNAL2 | c.1212-1027C>T | Intron (SNP) | VAF 6/74 reads (8%) | catalogued as rs1439633642; called by muse, mutect2
- PGR | c.*33del | 3'UTR (DEL) | VAF 10/47 reads (21%) | called by mutect2, pindel, varscan2
- TCFL5 | c.1381-3901T>G | Intron (SNP) | VAF 48/217 reads (22%) | called by mutect2, varscan2
